Somatic mutation profile of tumor specimen TARGET-40-NAAGJV-01A (aliquot TARGET-40-NAAGJV-01A-01D) from TARGET case TARGET-40-NAAGJV, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.8 years (5,784 days).
Specimen TARGET-40-NAAGJV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b60ea247-3a6f-4854-ac83-6e5dcb69a192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJV-10B (Blood Derived Normal), aliquot TARGET-40-NAAGJV-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0dfb034-5c19-43dc-92cb-8caceedf693e

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC242842.3 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 4/109 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1185110962; called by muse, mutect2
- ATP2B1 | c.2041G>C p.G681R | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53814964; called by muse, mutect2
- PI4KA | c.2236C>G p.R746G | Missense Mutation (SNP) | VAF 91/437 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV55412213; called by muse, mutect2, varscan2
- SLC43A3 | c.1267G>A p.G423S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100725208; called by muse, mutect2
- SRA1 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1313668405; called by muse, mutect2, varscan2
- SSTR3 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142693615; called by muse, mutect2, varscan2
- TSHZ2 | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61589307; called by muse, mutect2, varscan2
- AUTS2 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- CBLIF | c.393_416delinsTAGA p.F132Rfs*10 | Frame Shift Del (DEL) | VAF 61/210 reads (29%) | called by pindel, varscan2*
- HGD | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 25/236 reads (11%) | called by muse, mutect2, varscan2
- KDR | c.3851G>C p.G1284A | Missense Mutation (SNP) | VAF 758/2253 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYLK4 | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2
- NEXMIF | c.4105A>T p.I1369L | Missense Mutation (SNP) | VAF 92/115 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIWIL2 | c.1352C>A p.T451K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- RHOV | c.404A>T p.Q135L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEMA3E | c.2266del p.E756Kfs*30 | Frame Shift Del (DEL) | VAF 30/241 reads (12%) | called by mutect2, pindel, varscan2
- SPEF2 | c.5098A>T p.T1700S | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIBAR1 | c.831C>T p.D277= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as rs200614366, COSV63898094; called by muse, mutect2, varscan2
- CYP2A13 | c.39C>A p.A13= | Silent (SNP) | VAF 14/56 reads (25%) | called by mutect2, varscan2
- FREM2 | c.7380G>A p.T2460= | Silent (SNP) | VAF 146/204 reads (72%) | catalogued as rs372635207; ClinVar: likely benign; called by muse, mutect2, varscan2
- KDR | c.3987G>C p.L1329= | Silent (SNP) | VAF 876/2495 reads (35%) | catalogued as COSV55771413; called by muse, mutect2, varscan2
- KMT2B | c.4737T>G p.R1579= | Silent (SNP) | VAF 47/308 reads (15%) | called by muse, mutect2, varscan2
- UBE2DNL | n.263C>A | RNA (SNP) | VAF 21/26 reads (81%) | called by muse, mutect2, varscan2
